Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3581, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3581-01A (Primary Tumor).

Diagnosis/diagnoses:

Resected colon and rectum show tumor-free oral and aboral resection margins and the inclusion an ulcerated, moderately differentiated adenocarcinoma with infiltration of the lamina muscularis and without regional lymph node metastases (G2, pT2, pN0 0/33 L0 V0 R0).

Source: NCI Genomic Data Commons file a133f18c-6006-4d0f-b87f-4357ef63caa6 (TCGA-AG-3581.E064E84C-FFB3-4E29-BEE9-49A84C4B8756.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).